Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAI2, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAI2-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 3.0 cm; no angio-invasion; no rete testis available; no invasion of tunica albuginea; epididymis and spermatic cord not present in the available slides.

Date of procurement (= date of orchidectomy):

ICD 0-3

Seminoma NGS 9061/3

Site: R Testis NGS

062.9

9/3/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file d82d1c6b-12f4-4690-852d-232338c978d8 (TCGA-2G-AAI2-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).